Somatic mutation profile of tumor specimen BA2789D (aliquot aq-BA2789D) from BEATAML1.0 case 2141, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Therapy related myeloid neoplasm; Tissue or organ of origin: Bone marrow; Age at diagnosis: 67.0 years (24,456 days).
Specimen BA2789D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9a378826-0b28-4a5b-8d31-b4eb505ac161.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2780D (Solid Tissue Normal), aliquot aq-BA2780D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9fcd8a58-0f75-47e5-92b9-29e46076e5d9

The open-access MAF lists 3 somatic variants for this specimen: 1 protein-altering or splice-affecting, 2 silent.
By variant classification: Silent 2, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- INAVA | c.1136C>T p.P379L | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- CCDC151 | c.1302G>T p.A434= | Silent (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- PKD1L2 | c.507G>T p.V169= | Silent (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2
